Somatic mutation profile of tumor specimen TCGA-AO-A0JI-01A (aliquot TCGA-AO-A0JI-01A-21W-A100-09) from TCGA case TCGA-AO-A0JI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.7 years (20,694 days).
Specimen TCGA-AO-A0JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b09dddaf-f343-4e50-b324-178d456cfe50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JI-10A (Blood Derived Normal), aliquot TCGA-AO-A0JI-10A-01W-A100-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a1ec6dd-7447-4477-8ef4-98b15ff4f920

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH11 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 94/140 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749755929, COSV51764124; called by muse, mutect2, varscan2
- CDH17 | c.1932dup p.S645Vfs*18 | Frame Shift Ins (INS) | VAF 54/175 reads (31%) | catalogued as rs749875970; called by mutect2, pindel, varscan2
- GSPT2 | c.1631A>C p.H544P | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214727; called by muse, mutect2, varscan2
- LIPK | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562671234, COSV101344955; called by muse, mutect2
- MCMBP | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745417954, COSV62819870; called by muse, mutect2, varscan2
- NIM1K | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 106/270 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534141752, COSV58143849; called by muse, mutect2, varscan2
- OR2G3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 233/569 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.29); catalogued as COSV60682453; called by muse, mutect2, varscan2
- OR2T33 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV58816620; called by muse, varscan2
- OVCH1 | c.2625G>A p.W875* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | catalogued as COSV58965901; called by muse, mutect2, varscan2
- PRICKLE2 | c.1270G>A p.D424N (on ENST00000295902; = p.D368N on NM_198859.4) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.844); catalogued as rs544405738, COSV55766158, COSV55769414; called by muse, mutect2, varscan2
- PTAR1 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61207921, COSV61208861, COSV61209060; called by muse, mutect2, varscan2
- SLC4A4 | c.3100T>C p.S1034P (on ENST00000264485 / NM_001098484.3; = p.S990P on NM_003759.4) | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV52631374; called by muse, mutect2, varscan2
- SYNPO2L | c.1183C>T p.R395C (on ENST00000394810 / NM_001114133.3; = p.R171C on NM_024875.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65738220; called by muse, mutect2, varscan2
- TP53TG5 | c.48+1G>C p.X16_splice | Splice Site (SNP) | VAF 12/376 reads (3%) | catalogued as COSV101022314; called by muse, mutect2
- COL7A1 | c.6993C>T p.D2331= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs750379606, COSV60399090; called by muse, mutect2, varscan2
- MAP7D3 | c.2496C>A p.S832= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs1007827211, COSV100286212; called by muse, mutect2
- SLC45A4 | c.1008C>T p.H336= (on ENST00000517878 / NM_001286646.2; = p.H285= on NM_001080431.2) | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs774118130, COSV50150759; called by muse, mutect2, varscan2
- WNK1 | c.2140-2745_2140-2734del | Intron (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
